Somatic mutation profile of tumor specimen TCGA-D1-A3DG-01A (aliquot TCGA-D1-A3DG-01A-11D-A19Y-09) from TCGA case TCGA-D1-A3DG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 81.5 years (29,771 days).
Specimen TCGA-D1-A3DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 270542e2-bc5c-4732-9bff-8cf01a6b03ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A3DG-10A (Blood Derived Normal), aliquot TCGA-D1-A3DG-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08c8e438-c491-4a09-bc73-5d31692f4594

The open-access MAF lists 115 somatic variants for this specimen: 84 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 26, Frame Shift Del 5, Nonsense Mutation 3, RNA 3, Splice Site 2, Intron 2, Translation Start Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1745+1del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 24/56 reads (43%) | hotspot (GDC flag); catalogued as COSV57129726; called by mutect2, pindel*, varscan2
- RB1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 34/39 reads (87%) | catalogued as rs587778842, CM951104, COSV57299867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2632C>G p.Q878E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100383374, COSV60627707; called by muse, mutect2
- AKAP7 | c.877G>A p.D293N (on ENST00000431975 / NM_016377.4; = p.D26N on NM_004842.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs1474611142, COSV99541726; called by muse, mutect2, varscan2
- AMER1 | c.2204C>A p.A735E | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100366888; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV51846737, COSV99784141; called by muse, mutect2, varscan2
- ARHGAP20 | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99502868, COSV99505009; called by muse, mutect2, varscan2
- ARHGAP35 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV101351483; called by muse, mutect2, varscan2
- ARHGEF40 | c.4528C>G p.R1510G | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100070617; called by muse, mutect2
- ARMCX6 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100726252; called by muse, mutect2, varscan2
- BGN | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs1556993715, COSV100525263; called by muse, mutect2, varscan2
- C12orf66 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369744797; called by muse, mutect2, varscan2
- C8A | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV100776644; called by muse, mutect2, varscan2
- CAMK2D | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99594584; called by muse, mutect2, varscan2
- CDC42BPA | c.2800G>A p.D934N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV100506397; called by muse, mutect2, varscan2
- CELF3 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs370209956; called by muse, mutect2, varscan2
- CSMD3 | c.5323T>C p.S1775P (on ENST00000297405 / NM_001363185.1; = p.S1671P on NM_052900.3) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99843979; called by muse, mutect2, varscan2
- CTAG2 | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99909144; called by muse, mutect2
- DDX50 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.038); catalogued as COSV101007300; called by muse, mutect2, varscan2
- DNAH2 | c.2039G>C p.R680T | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101209537; called by muse, mutect2, varscan2
- DPY30 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99705086; called by muse, mutect2, varscan2
- EGFL7 | c.282G>T p.R94S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100452040; called by muse, mutect2, varscan2
- EYA2 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427199; called by muse, mutect2, varscan2
- FAM98A | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); catalogued as rs1416807878, COSV99479489; called by muse, mutect2, varscan2
- FBXO32 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV54890616; called by muse, mutect2, varscan2
- FUZ | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV100571239; called by muse, mutect2, varscan2
- GALR1 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV100231952, COSV100232056; called by muse, mutect2, varscan2
- GGT1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 78/86 reads (91%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs548087574, COSV99959223, COSV99959418; called by muse, mutect2, varscan2
- GRIK2 | c.1349A>T p.D450V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100028479; called by muse, mutect2, varscan2
- GTF2I | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100259835; called by muse, mutect2, varscan2
- HOOK2 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99317796; called by muse, mutect2, varscan2
- IFI35 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV99887924; called by muse, mutect2, varscan2
- INO80B | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as rs767696148, COSV51969190; called by muse, mutect2, varscan2
- KIAA0319 | c.2192T>C p.L731P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141223480; called by muse, mutect2, varscan2
- KIAA1217 | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 25/42 reads (60%) | catalogued as COSV100287097; called by muse, mutect2, varscan2
- KIRREL2 | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV99384308; called by muse, mutect2, varscan2
- KLHL30 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV100014508; called by muse, mutect2, varscan2
- KMT5B | c.2222C>G p.S741C | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430394, COSV58569833; called by muse, mutect2, varscan2
- KRT36 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100057693; called by muse, mutect2, varscan2
- LILRA4 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as COSV99393317; called by muse, mutect2, varscan2
- MRTFA | c.2579-2A>C p.X860_splice | Splice Site (SNP) | VAF 13/20 reads (65%) | catalogued as COSV99960615; called by muse, mutect2, varscan2
- MTERF2 | c.956C>A p.T319K | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.279); catalogued as COSV99526958; called by muse, mutect2, varscan2
- MYO10 | c.2367A>C p.K789N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV57017997, COSV99946038; called by muse, mutect2, varscan2
- MYO7B | c.5470G>T p.V1824L | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100264903; called by muse, mutect2, varscan2
- NACC1 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99457179, COSV99457208; called by muse, mutect2, varscan2
- NEU2 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99290695; called by muse, mutect2, varscan2
- NKAPL | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642566; called by muse, mutect2, varscan2
- NPHP3 | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100447256; called by muse, mutect2, varscan2
- OR5K2 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV101415976; called by muse, mutect2, varscan2
- PENK | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767796107, COSV59240443; called by muse, mutect2, varscan2
- PLEKHG3 | c.403G>A p.V135M (on ENST00000394691; = p.V191M on NM_001308147.2) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1303477171, COSV99906979; called by muse, mutect2
- PNCK | c.165G>C p.E55D (on ENST00000340888 / NM_001366975.1; = p.E138D on NM_001039582.3) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.325); catalogued as COSV100562439; called by muse, mutect2, varscan2
- PPFIA1 | c.2858C>G p.S953C | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99557913; called by muse, mutect2, varscan2
- RBM39 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99488823; called by muse, mutect2, varscan2
- RNF43 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101348515; called by muse, mutect2, varscan2
- RP2 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV99509258; called by muse, mutect2, varscan2
- RYR3 | c.13255G>T p.V4419L (on ENST00000389232; = p.V4420L on NM_001036.6) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as COSV101213868; called by muse, mutect2, varscan2
- SEPTIN2 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100764899, COSV100764984, COSV63472460; called by muse, mutect2, varscan2
- SERPINF2 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132064; called by muse, mutect2
- SH2D7 | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99363434; called by muse, mutect2, varscan2
- SPARC | c.670T>G p.Y224D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99163860; called by muse, mutect2, varscan2
- STAB1 | c.766C>G p.Q256E | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100402092, COSV58740845; called by muse, mutect2, varscan2
- STAB1 | c.1401C>G p.D467E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV100402093; called by muse, mutect2, varscan2
- STAG1 | c.763A>T p.R255* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV99366634; called by muse, mutect2, varscan2
- STAG3 | c.146A>G p.D49G | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99445007; called by muse, mutect2, varscan2
- SYNE1 | c.2633G>T p.S878I (on ENST00000367255 / NM_182961.4; = p.S885I on NM_033071.3) | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV99575084; called by muse, mutect2, varscan2
- THSD1 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 67/74 reads (91%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1202013298, COSV99318705; called by muse, mutect2, varscan2
- TTLL9 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs765491899, COSV60590092; called by muse, mutect2, varscan2
- USH2A | c.13790A>T p.N4597I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV56445630; called by muse, mutect2
- VPS33B | c.420A>T p.E140D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV100325706; called by muse, mutect2, varscan2
- WNT5A | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99224998; called by muse, mutect2, varscan2
- XIRP2 | c.4055G>T p.W1352L (on ENST00000628543; = p.W1527L on NM_152381.6) | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746269; called by muse, mutect2, varscan2
- YEATS4 | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99924091; called by muse, mutect2, varscan2
- ZNF518A | c.2292C>G p.I764M | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283655; called by muse, mutect2, varscan2
- ZNF81 | c.486T>A p.N162K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100096061; called by muse, mutect2, varscan2
- ARHGAP35 | c.739_749del p.I247Sfs*11 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- FBXL4 | c.162_174del p.Y54* | Frame Shift Del (DEL) | VAF 27/55 reads (49%) | called by mutect2, pindel, varscan2
- FRYL | c.5432_5437del p.E1811_V1812del | In Frame Del (DEL) | VAF 14/39 reads (36%) | called by pindel, varscan2
- FRYL | c.5426T>A p.L1809H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- IGHG1 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MGA | c.1903_1933del p.S635Afs*9 | Frame Shift Del (DEL) | VAF 32/45 reads (71%) | called by mutect2, pindel, varscan2
- ROS1 | c.3542_3554del p.E1181Vfs*58 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- TACC3 | c.688_691del p.H230Efs*84 | Frame Shift Del (DEL) | VAF 30/47 reads (64%) | called by mutect2, pindel
- TSPYL4 | c.824_825insTT p.M275Ifs*3 | Frame Shift Ins (INS) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- ADAM8 | c.1965C>T p.P655= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs535345577, COSV101291724; called by muse, mutect2, varscan2
- ARMC1 | c.408A>G p.G136= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV99395132; called by muse, mutect2, varscan2
- DOP1A | c.6273C>G p.V2091= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as COSV99382683; called by muse, mutect2, varscan2
- DYNC1LI2 | c.678G>A p.P226= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as rs759894387, COSV50755123, COSV99263209; called by muse, mutect2, varscan2
- ELF4 | c.15A>T p.L5= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as COSV100257544; called by muse, mutect2, varscan2
- GLT8D1 | c.1095C>G p.T365= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV99804052; called by muse, mutect2, varscan2
- HOXA3 | c.264G>A p.P88= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV100415636; called by muse, mutect2, varscan2
- IGHV3-53 | c.141C>T p.T47= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs781992517; called by muse, mutect2
- IGHV3-66 | c.141C>T p.T47= | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as rs782347421; called by muse, mutect2
- LCE2A | c.195C>T p.G65= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs61812675, COSV64227204; called by muse, mutect2, varscan2
- ODF1 | c.387G>A p.V129= | Silent (SNP) | VAF 51/103 reads (50%) | catalogued as COSV99574353; called by muse, mutect2, varscan2
- OR1I1 | c.822C>T p.A274= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs372348714; called by muse, mutect2, varscan2
- PAM | c.1293A>G p.Q431= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV57214921, COSV99173732; called by muse, mutect2, varscan2
- PCDH15 | c.4692C>T p.I1564= (on ENST00000644397 / NM_001354429.2; = p.I1506= on NM_001142771.2) | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100905384; called by muse, mutect2, varscan2
- PLPPR4 | c.1197T>C p.I399= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100926896; called by muse, mutect2, varscan2
- POMT1 | c.585C>T p.V195= | Silent (SNP) | VAF 76/174 reads (44%) | catalogued as rs764110407, COSV61228271; called by muse, mutect2, varscan2
- PTPRD | c.2190C>T p.V730= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV100646183; called by muse, mutect2, varscan2
- RUSC1 | c.1029C>T p.L343= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99429357; called by muse, mutect2, varscan2
- RYR2 | c.4413T>C p.D1471= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV100772209; called by muse, mutect2, varscan2
- SLC20A1 | c.1326C>T p.G442= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as rs770364998, COSV99734198; called by muse, mutect2, varscan2
- SMARCAD1 | c.2370A>G p.Q790= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as rs746290982, COSV100759015; called by muse, mutect2, varscan2
- SP100 | c.2352C>G p.R784= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99893982; called by muse, mutect2, varscan2
- TCERG1 | c.246A>G p.P82= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99695167; called by muse, mutect2, varscan2
- TRAPPC8 | c.117C>T p.F39= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1424235559, COSV99351805; called by muse, mutect2
- USH2A | c.13788A>T p.V4596= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV100240418; called by muse, mutect2
- VPS41 | c.2388C>A p.S796= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100054177; called by muse, mutect2, varscan2
- BCL2A1 | c.420+3016G>T | Intron (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99144358; called by muse, mutect2, varscan2
- CCM2 | c.31-10523G>A | Intron (SNP) | VAF 19/27 reads (70%) | catalogued as rs369487153; called by muse, mutect2, varscan2
- LINC00174 | n.3222C>T | RNA (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2
- SNORD116-20 | n.77C>T | RNA (SNP) | VAF 44/51 reads (86%) | catalogued as rs764299146; called by muse, mutect2, varscan2
- SSPOP | n.7016C>T | RNA (SNP) | VAF 46/94 reads (49%) | catalogued as rs1303810661, COSV100022869, COSV50489582; called by muse, mutect2, varscan2
